Gene-level copy-number profile of tumor specimen C3N-02788-01 from CPTAC case C3N-02788, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.7 years (23,634 days).
Specimen C3N-02788-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a0aa4603-555d-42f8-bea1-ac1d1c306d76.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02788-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/76703ac8-adae-4376-a76d-3bce06a7c256

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 12,950; copy number 2: 42,057; copy number 3: 3,567; copy number 4: 5; copy number 6: 3; copy number 8: 78; copy number 9: 111; copy number 10: 70; copy number 11: 26.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:74,198,212–74,234,086, 1 gene (within-gene range 0–2): FPGT.
- chr2:89,330,110–89,600,680, 2 genes: IGKV2-40, 5S_rRNA.
- chr2:189,133,036–189,133,111, 1 gene (within-gene range 0–2): MIR3129.
- chr3:28,315,003–28,349,050, 1 gene (within-gene range 0–1): AZI2.
- chr3:109,915,976–109,916,940, 1 gene: NFYBP1.
- chr5:86,353,803–86,368,854, 1 gene: AC016550.2.
- chr6:49,960,249–49,969,625, 2 genes: DEFB114, DEFB113.
- chr6:115,633,540–115,643,916, 1 gene: LINC02534.
- chr7:9,621,764–9,769,513, 1 gene (within-gene range 0–2): AC060834.2.
- chr8:89,757,806–89,791,064, 1 gene: RIPK2.
- chr9:21,409,117–21,441,316, 4 genes: IFNA8, AL353732.2, IFNWP2, IFNA1.
- chr9:21,455,484–21,482,313, 2 genes (within-gene range 0–1): IFNWP19, IFNE.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr10:65,054,460–65,055,003, 1 gene: NEK4P3.
- chr10:87,607,985–88,259,372, 14 genes: AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr11:81,842,435–81,842,669, 1 gene: AP002802.2.
- chr11:90,193,614–90,198,120, 1 gene: AP000648.4.
- chr11:95,768,953–95,790,409, 1 gene (within-gene range 0–2): FAM76B.
- chr12:85,280,220–85,342,912, 2 genes: ALX1, LINC02820.
- chr13:56,214,373–56,216,942, 1 gene: SPATA2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 288 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,441,789–184,135,238, 276 genes, copy number 8–11 (within-gene range 1–11) (broad region; genes not listed).
- chr3:184,230,429–184,249,548, 3 genes, copy number 9 (within-gene range 1–9): VWA5B2, MIR1224, ALG3.
- chr3:184,249,695–184,293,031, 2 genes, copy number 9 (within-gene range 1–9): EEF1AKMT4-ECE2, CAMK2N2.
- chr3:184,314,495–184,361,650, 4 genes, copy number 9 (within-gene range 1–9): EIF4G1, SNORD66, FAM131A, CLCN2.
- chr14:18,333,726–18,412,264, 3 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2.

Autosomal genes at a single copy (total copy number 1): 10,632. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
